Somatic mutation profile of tumor specimen C3N-00852-02 (aliquot CPT0024660012) from CPTAC case C3N-00852, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 62.2 years (22,718 days).
Specimen C3N-00852-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ea5370f-ad55-4025-a1ac-2e76dd027101.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00852-71 (Blood Derived Normal), aliquot CPT0024740002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82aa7e46-7465-4750-99aa-8fec8a2bdb01

The open-access MAF lists 79 somatic variants for this specimen: 52 protein-altering or splice-affecting, 12 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 12, Intron 9, Frame Shift Del 8, Nonsense Mutation 3, 5'Flank 3, Splice Site 2, RNA 2, In Frame Ins 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP3M2 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 55/168 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51530271; called by muse, mutect2, varscan2
- COL24A1 | c.2866C>A p.H956N | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.024); catalogued as rs1157875253; called by muse, mutect2, varscan2
- DNAJB2 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1252580169; called by muse, mutect2, varscan2
- HSPA6 | c.1051T>A p.L351M | Missense Mutation (SNP) | VAF 135/336 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.99); catalogued as rs1179945729, COSV100554302, COSV59062758; called by muse, mutect2, varscan2
- INPP5F | c.1351G>T p.E451* | Nonsense Mutation (SNP) | VAF 43/121 reads (36%) | catalogued as COSV100739974; called by muse, mutect2, varscan2
- KIF1B | c.4118G>A p.R1373Q (on ENST00000377086 / NM_001365952.1; = p.R1327Q on NM_015074.3) | Missense Mutation (SNP) | VAF 147/506 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs774615554; called by muse, mutect2, varscan2
- N4BP1 | c.2628G>T p.Q876H | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as COSV52210288; called by muse, mutect2, varscan2
- NDRG1 | c.602T>C p.M201T | Missense Mutation (SNP) | VAF 105/337 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs980031699; called by muse, mutect2, varscan2
- NPIPB11 | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 74/855 reads (9%) | catalogued as rs1248418769; called by muse, mutect2, varscan2
- OVGP1 | c.173T>A p.F58Y | Missense Mutation (SNP) | VAF 199/486 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755771009; called by muse, mutect2, varscan2
- PBRM1 | c.1443+1del p.X481_splice | Splice Site (DEL) | VAF 105/217 reads (48%) | catalogued as COSV56270634; called by mutect2, pindel, varscan2
- TOGARAM1 | c.4821_4824del p.L1607Ffs*12 | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | catalogued as rs749059577; called by pindel, varscan2
- TTN | c.3121G>A p.E1041K (on ENST00000591111; = p.E995K on NM_003319.4) | Missense Mutation (SNP) | VAF 27/256 reads (11%) | PolyPhen benign (0.013); catalogued as rs201869200, COSV60034296; called by muse, mutect2, varscan2
- VHL | c.469del p.T157Lfs*2 | Frame Shift Del (DEL) | VAF 189/426 reads (44%) | catalogued as COSV56565821; called by mutect2, pindel, varscan2
- AASDH | c.1913del p.F638Sfs*30 | Frame Shift Del (DEL) | VAF 15/85 reads (18%) | called by mutect2, pindel, varscan2
- ACACB | c.6034dup p.Y2012Lfs*6 | Frame Shift Ins (INS) | VAF 14/63 reads (22%) | called by mutect2, pindel
- ALOX12B | c.1441C>T p.L481F | Missense Mutation (SNP) | VAF 63/496 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- ARHGEF3 | c.1456_1458dup p.M486dup | In Frame Ins (INS) | VAF 106/216 reads (49%) | called by mutect2, pindel, varscan2
- ATP6V0A1 | c.665_674del p.I222Kfs*5 | Frame Shift Del (DEL) | VAF 22/71 reads (31%) | called by mutect2, pindel, varscan2
- ATXN2L | c.616G>C p.D206H | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAPN5 | c.1811T>A p.V604E (on ENST00000456580; = p.V564E on NM_004055.5) | Missense Mutation (SNP) | VAF 43/304 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- COL28A1 | c.2515A>C p.I839L | Missense Mutation (SNP) | VAF 207/462 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- CSF1R | c.148T>C p.W50R | Missense Mutation (SNP) | VAF 165/850 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLGAP2 | c.1738T>A p.Y580N | Missense Mutation (SNP) | VAF 83/287 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ERH | c.232A>C p.T78P | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- FLII | c.2047G>T p.E683* | Nonsense Mutation (SNP) | VAF 65/189 reads (34%) | called by muse, mutect2, varscan2
- FOXP2 | c.1229A>T p.H410L | Missense Mutation (SNP) | VAF 122/426 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- FSIP2 | c.13502del p.N4501Ifs*9 | Frame Shift Del (DEL) | VAF 7/17 reads (41%) | called by mutect2, pindel, varscan2
- GJA9 | c.872A>C p.Q291P | Missense Mutation (SNP) | VAF 55/109 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HIVEP3 | c.1903G>T p.G635C | Missense Mutation (SNP) | VAF 87/342 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- IGSF11 | c.220A>G p.I74V (on ENST00000393775 / NM_001015887.3; = p.I73V on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.873); called by muse, varscan2
- IL4R | c.1912A>T p.I638F | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ISG20L2 | c.670G>T p.D224Y | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KDM5C | c.1549G>T p.D517Y | Missense Mutation (SNP) | VAF 168/233 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF7 | c.1405G>A p.V469I | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NLGN2 | c.602T>A p.L201Q | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- NTF3 | c.770del p.T257Nfs*14 | Frame Shift Del (DEL) | VAF 72/274 reads (26%) | called by mutect2, pindel, varscan2
- ODAM | c.56T>G p.I19S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); called by muse, varscan2
- OR7A5 | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 86/316 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PLIN2 | c.449A>G p.E150G | Missense Mutation (SNP) | VAF 67/339 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PPP1R3B | c.476C>G p.T159S | Missense Mutation (SNP) | VAF 107/372 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- R3HDM1 | c.2645T>A p.L882H | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- RNF157 | c.297-1G>T p.X99_splice | Splice Site (SNP) | VAF 28/103 reads (27%) | called by muse, mutect2, varscan2
- RUNX2 | c.1060T>C p.S354P | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- SLC13A1 | c.1333C>G p.L445V | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); called by muse, mutect2
- SSC5D | c.1079G>A p.G360E | Missense Mutation (SNP) | VAF 96/178 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBC1D19 | c.1032del p.Y344* | Frame Shift Del (DEL) | VAF 13/56 reads (23%) | called by mutect2, pindel*, varscan2*
- TRA2B | c.710_714del p.S237Ifs*23 | Frame Shift Del (DEL) | VAF 58/165 reads (35%) | called by mutect2, pindel, varscan2
- TRPV6 | c.2024A>T p.D675V | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- TTN | c.18011T>A p.I6004N (on ENST00000591111; = p.I5077N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/50 reads (14%) | PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- XYLB | c.45C>G p.F15L | Missense Mutation (SNP) | VAF 83/149 reads (56%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF597 | c.382C>G p.P128A | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- CDC16 | c.1525A>C p.R509= | Silent (SNP) | VAF 35/104 reads (34%) | called by muse, mutect2, varscan2
- GPATCH1 | c.36G>C p.L12= | Silent (SNP) | VAF 45/399 reads (11%) | called by muse, mutect2, varscan2
- GPR162 | c.630C>A p.P210= | Silent (SNP) | VAF 63/188 reads (34%) | called by muse, mutect2, varscan2
- MAGI3 | c.3070C>T p.L1024= | Silent (SNP) | VAF 47/152 reads (31%) | called by muse, mutect2, varscan2
- MYPN | c.714G>A p.A238= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as rs757661676; ClinVar: likely benign; called by muse, mutect2, varscan2
- PHF23 | c.930A>G p.Q310= | Silent (SNP) | VAF 80/173 reads (46%) | called by muse, mutect2, varscan2
- PLK1 | c.978G>T p.S326= | Silent (SNP) | VAF 62/455 reads (14%) | called by muse, mutect2, varscan2
- R3HDM2 | c.1257C>A p.P419= | Silent (SNP) | VAF 136/290 reads (47%) | called by muse, varscan2
- SGCB | c.870T>C p.C290= | Silent (SNP) | VAF 90/254 reads (35%) | called by muse, mutect2, varscan2
- TAOK1 | c.414A>G p.G138= | Silent (SNP) | VAF 12/41 reads (29%) | called by mutect2, varscan2
- TTC21B | c.2805T>C p.D935= | Silent (SNP) | VAF 159/593 reads (27%) | called by muse, mutect2, varscan2
- ZNF217 | c.792C>T p.D264= | Silent (SNP) | VAF 36/238 reads (15%) | catalogued as rs563819509; called by muse, mutect2, varscan2
- BNIP1 | c.490+785G>T | Intron (SNP) | VAF 15/181 reads (8%) | called by muse, mutect2
- CZIB | c.6+100G>T | Intron (SNP) | VAF 60/247 reads (24%) | called by muse, mutect2, varscan2
- DPY19L2P2 | n.506C>G | RNA (SNP) | VAF 75/173 reads (43%) | called by muse, mutect2, varscan2
- DZANK1 | c.543+749G>T | Intron (SNP) | VAF 17/73 reads (23%) | called by muse, mutect2, varscan2
- EIF2B1 | c.482+170G>A | Intron (SNP) | VAF 42/150 reads (28%) | called by muse, mutect2, varscan2
- EPB41L3 | chr18:5630404 C>A | 5'Flank (SNP) | VAF 146/373 reads (39%) | catalogued as rs1272227389; called by muse, mutect2, varscan2
- FLT4 | c.3332-22del | Intron (DEL) | VAF 32/126 reads (25%) | catalogued as COSV99988381; called by mutect2, pindel, varscan2
- GGT7 | c.1726-126G>A | Intron (SNP) | VAF 65/233 reads (28%) | catalogued as rs760483256; called by muse, mutect2, varscan2
- HLA-L | n.992G>C | RNA (SNP) | VAF 14/145 reads (10%) | called by muse, mutect2
- INPP5B | c.772+13G>A | Intron (SNP) | VAF 90/207 reads (43%) | called by muse, mutect2, varscan2
- JPH3 | chr16:87701797 ins C | 3'Flank (INS) | VAF 82/331 reads (25%) | called by mutect2, pindel, varscan2
- RPS6KA1 | c.109-928G>C | Intron (SNP) | VAF 137/343 reads (40%) | called by muse, mutect2, varscan2
- SRRM2 | c.690-44T>A | Intron (SNP) | VAF 30/96 reads (31%) | called by muse, mutect2, varscan2
- WT1 | chr11:32439083 C>T | 5'Flank (SNP) | VAF 97/189 reads (51%) | called by muse, mutect2, varscan2
- WT1 | chr11:32439084 T>A | 5'Flank (SNP) | VAF 98/190 reads (52%) | called by muse, mutect2, varscan2
